Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4619, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4619-01A (Primary Tumor).

[page 1 of 4]
Diagnosis:

Kidney, left, left radical nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, conventional type

Histologic grade (if applicable): grade 2 of 4

Tumor size (greatest dimension): 3.4 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: not involved

Gerota's fascia: not involved

Renal vein: not involved

Ureter: not involved

Venous (large vessel): not involved

Lymphatic (small vessel): not involved

Adjacent organs: not involved

Histologic assessment of surgical margins:

Perirenal adipose tissue: not involved

Gerota's fascia: not involved

Renal vein: not involved

Renal artery: not involved

Ureter: not involved

Adrenal gland: present and unremarkable

Lymph nodes: none present

Other significant findings:

- Patchy interstitial chronic inflammation.

- Incidental papillary adenoma, 0.2 cm (see comment).

AJCC Staging:

pT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

COMMENT:

Immunohistochemical stains were performed on blocks A3 and A4. The tumor cells in the dominant mass are negative for CK7, CK20 and Hale's colloidal iron. These findings exclude the possibility of chromophobe variant of renal cell carcinoma. A second focus in block A3 shows a papillary neoplasm with psammoma bodies that is 0.2 cm in greatest dimension. It is positive for CK7 and negative for CK20, TTF-1, and thyroglobulin. These findings exclude the possibility of a micrometastasis from lung or thyroid. The findings are consistent with a papillary microadenoma.

Clinical History:

with clinical diagnosis of renal mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: per the specimen requisition, a laparoscopic radical nephrectomy

Side of specimen: left

Size and weight of specimen: 1,000 grams; 25 x 23 x 9 cm overall; The kidney is 14.0 x 7.0 x 6.5 cm.

Orientation: There is no orientation provided. The external surface is inked blue.

Presence/absence of adrenal gland: A markedly disrupted 1.0 x 0.4 x 0.2 cm area of golden brown tissue suggestive of adrenal gland is identified at the superior pole of the nephrectomy specimen. This is the only identified adrenal gland.

Tumor description/site: The tumor is an upper pole, mainly anterior medial mass. The mass appears cortical and has a mainly solid, but focally cystic pink/brown, focally hemorrhagic cut surface. The appearance is not suggestive of classic renal cell.

[page 2 of 4]
Tumor size: 3.4 x 2.8 x 1.5 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: Grossly confined, however the perinephric adipose tissue is disrupted overlying the tumor. At one portion, the kidney is inked blue.

Extent of invasion:

Perirenal adipose tissue: difficult to accurately determined, believed to be uninvolved

Gerota's fascia: does not grossly involve

Renal vein: does not grossly involve

Ureter: does not grossly involve

Other organs: tumor is distant from the small fragment of adrenal gland

Surgical margins:

Perirenal adipose tissue: believed negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Description of kidney away from tumor: The remainder of the kidney parenchyma consists of pink/brown normal parenchyma with a distant corticomedullary junction. The cortex is 9 mm and the medulla is 1.1 cm. The medulla is 1.1 cm.

Lymph nodes (hilar): The hilar adipose tissue is palpated for lymph node candidate, no lymph node candidates are identified.

Other significant findings: none

Tissue submitted for special investigations: Tumor and normal was taken by Tissue Procurement

Digital photograph taken: no

Block summary:

A1 - ureter and hilar vascular margins, en face

A2 - adrenal gland

A3 - normal kidney

4, A5 - one section of kidney and blue inked margin, slice bisected

5, A7 - additional kidney and blue inked margin, slice bisected

A8 - tumor and adjacent normal cortex

A9 - tumor towards renal pelvis

A10 - tumor in the area of the renal sinus

Light Microscopy:

Light microscopic examination is performed by [REDACTED].

Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the [REDACTED].

[REDACTED]. These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

[page 3 of 4]
diagnosis:

Kidney, left, left radical nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, conventional type

Histologic grade (if applicable): grade 2 of 4

Tumor size (greatest dimension): 3.4 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: not involved

Gerota's fascia: not involved

Renal vein: not involved

Ureter: not involved

Venous (large vessel): not involved

Lymphatic (small vessel): not involved

Adjacent organs: not involved

Histologic assessment of surgical margins:

Perirenal adipose tissue: not involved

Gerota's fascia: not involved

Renal vein: not involved

Renal artery: not involved

Ureter: not involved

Adrenal gland: present and unremarkable

Lymph nodes: none present

Other significant findings:

- Patchy interstitial chronic inflammation.
- Incidental papillary adenoma, 0.2 cm (see comment).

JCC Staging:

pT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

COMMENT:

Immunohistochemical stains were performed on blocks A3 and A4. The tumor cells in the dominant mass are negative for CK7, CK20 and Hale's colloidal iron. These findings exclude the possibility of chromophobe variant of renal cell carcinoma. A second focus in block A3 shows a papillary neoplasm with psammoma bodies that is 0.2 cm in greatest dimension. It is positive for CK7 and negative for CK20, TTF-1, and thyroglobulin. These findings exclude the possibility of a micrometastasis from lung or thyroid. The findings are consistent with a papillary microadenoma.

Clinical History:

with clinical diagnosis of renal mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: per the specimen requisition, a laparoscopic radical nephrectomy

Side of specimen: left

Size and weight of specimen: 1,000 grams; 25 x 23 x 9 cm overall; The kidney is 14.0 x 7.0 x 6.5 cm.

Orientation: There is no orientation provided. The external surface is inked blue.

Presence/absence of adrenal gland: A markedly disrupted 1.0 x 0.4 x 0.2 cm area of golden brown tissue suggestive of adrenal gland is identified at the superior pole of the nephrectomy specimen. This is the only identified adrenal gland.

Tumor description/site: The tumor is an upper pole, mainly anterior medial mass. The mass appears cortical and has a mainly solid, but focally cystic pink/brown, focally hemorrhagic cut surface. The appearance is not suggestive of classic renal cell.

[page 4 of 4]
Tumor size: 3.4 x 2.8 x 1.5 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: Grossly confined, however the perinephric adipose tissue is disrupted overlying the tumor. At one portion, the kidney is inked blue.

Extent of invasion:

Perirenal adipose tissue: difficult to accurately determined, believed to be uninvolved

Gerota's fascia: does not grossly involve

Renal vein: does not grossly involve

Ureter: does not grossly involve

Other organs: tumor is distant from the small fragment of adrenal gland

Surgical margins:

Perirenal adipose tissue: believed negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Description of kidney away from tumor: The remainder of the kidney parenchyma consists of pink/brown normal parenchyma with a distant corticomedullary junction. The cortex is 9 mm and the medulla is 1.1 cm. The medulla is 1.1 cm.

Lymph nodes (hilar): The hilar adipose tissue is palpated for lymph node candidate, no lymph node candidates are identified.

Other significant findings: none

Tissue submitted for special investigations: Tumor and normal was taken by Tissue Procurement

Digital photograph taken: no

Block summary:

A1 - ureter and hilar vascular margins, en face

A2 - adrenal gland

A3 - normal kidney

A4, A5 - one section of kidney and blue inked margin, slice bisected

A6, A7 - additional kidney and blue inked margin, slice bisected

A8 - tumor and adjacent normal cortex

A9 - tumor towards renal pelvis

A10 - tumor in the area of the renal sinus

Light Microscopy:

Light microscopic examination is performed by Dr.

Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the [REDACTED]

[REDACTED] These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file c9dc99f8-371e-4738-b55f-b1923300bdc3 (TCGA-B8-4619.321F89B0-5AE4-487F-B3D2-6008B462B747.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).